Somatic mutation profile of tumor specimen TCGA-BF-A5EP-01A (aliquot TCGA-BF-A5EP-01A-12D-A27K-08) from TCGA case TCGA-BF-A5EP, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 75.6 years (27,622 days).
Specimen TCGA-BF-A5EP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eef3b1bb-ef2f-4bac-b2ef-a2b2181e579b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BF-A5EP-10A (Blood Derived Normal), aliquot TCGA-BF-A5EP-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4871e0fc-e741-4c29-b04e-e1e1d4e06c1c

The open-access MAF lists 192 somatic variants for this specimen: 135 protein-altering or splice-affecting, 55 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 122, Silent 55, Nonsense Mutation 8, Splice Region 2, Splice Site 2, Intron 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AADACL4 | c.916C>T p.P306S | Missense Mutation (SNP) | VAF 79/202 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.377); catalogued as COSV100879341; called by muse, mutect2, varscan2
- ABCC11 | c.3047G>A p.G1016E | Missense Mutation (SNP) | VAF 61/138 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.833); catalogued as COSV100750487; called by muse, mutect2, varscan2
- ADAMTS19 | c.2482G>A p.E828K | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT tolerated (0.15); PolyPhen benign (0.365); catalogued as COSV99176259; called by muse, mutect2, varscan2
- ADGRF2 | c.1991G>A p.G664E (on ENST00000296862 / NM_001368115.2; = p.G596E on NM_153839.7) | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs373612673, COSV99730614; called by muse, mutect2, varscan2
- ADGRL2 | c.2779T>C p.W927R (on ENST00000370717 / NM_001366005.1; = p.W914R on NM_012302.4) | Missense Mutation (SNP) | VAF 62/90 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99586916; called by muse, mutect2, varscan2
- ANKIB1 | c.2560C>T p.P854S | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99728231; called by muse, mutect2, varscan2
- ARPC2 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as COSV55286257; called by muse, mutect2, varscan2
- BMP2 | c.670C>A p.H224N | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as COSV101122049; called by muse, mutect2, varscan2
- C10orf120 | c.908C>T p.S303L | Missense Mutation (SNP) | VAF 69/92 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1487424360, COSV61491704; called by muse, mutect2, varscan2
- CBX4 | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV99490177; called by muse, mutect2, varscan2
- CDK5RAP2 | c.4987A>T p.S1663C | Missense Mutation (SNP) | VAF 43/50 reads (86%) | SIFT deleterious (0.04); PolyPhen benign (0.338); catalogued as COSV100575025; called by muse, mutect2, varscan2
- CEP250 | c.3971C>T p.S1324F | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs757984899, COSV61168410, COSV61171424; called by muse, mutect2, varscan2
- CHID1 | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 164/327 reads (50%) | SIFT tolerated (0.52); PolyPhen benign (0.011); catalogued as rs1487517317, COSV100059332; called by muse, mutect2, varscan2
- CHRM4 | c.96G>A p.M32I | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs200760652, COSV100708721; called by muse, mutect2, varscan2
- CMYA5 | c.5396C>T p.S1799L | Missense Mutation (SNP) | VAF 69/85 reads (81%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV101483779; called by muse, mutect2, varscan2
- CNOT6 | c.1670G>A p.R557K | Missense Mutation (SNP) | VAF 39/51 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV99993373; called by muse, mutect2, varscan2
- CPED1 | c.1492G>A p.V498I | Missense Mutation (SNP) | VAF 56/170 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV100119879; called by muse, mutect2, varscan2
- CSF2RB | c.2054G>A p.G685E | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.82); PolyPhen benign (0.01); catalogued as COSV99453195; called by muse, mutect2, varscan2
- CSMD1 | c.9947G>A p.R3316K (on ENST00000520002; = p.R3315K on NM_033225.6) | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as COSV100142921; called by muse, mutect2, varscan2
- CUBN | c.3343G>A p.E1115K | Missense Mutation (SNP) | VAF 44/51 reads (86%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV64709702; called by muse, mutect2, varscan2
- CUX1 | c.3131-1G>A p.X1044_splice | Splice Site (SNP) | VAF 133/324 reads (41%) | catalogued as COSV99470277; called by muse, mutect2, varscan2
- CYB5R2 | c.334G>C p.G112R | Missense Mutation (SNP) | VAF 83/191 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100207342, COSV55085060; called by muse, mutect2, varscan2
- CYP2J2 | c.49C>T p.H17Y | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.167); catalogued as COSV100967933; called by muse, mutect2
- DCC | c.3486G>A p.M1162I | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV71433464; called by muse, mutect2, varscan2
- DIAPH2 | c.132+1G>A p.X44_splice | Splice Site (SNP) | VAF 18/33 reads (55%) | catalogued as COSV100230451, COSV104411062; called by muse, mutect2, varscan2
- DLGAP1 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 73/179 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as COSV100227753; called by muse, mutect2, varscan2
- DSC1 | c.1950C>A p.D650E | Missense Mutation (SNP) | VAF 64/161 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99937102; called by muse, mutect2
- DSC1 | c.1948G>A p.D650N | Missense Mutation (SNP) | VAF 64/157 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99937104; called by muse, mutect2
- EIF5B | c.2230C>T p.L744F | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99176769; called by muse, mutect2, varscan2
- ELAVL4 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 92/216 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63917669; called by muse, mutect2, varscan2
- ELOVL4 | c.369G>A p.R123= | Splice Region (SNP) | VAF 29/60 reads (48%) | catalogued as COSV63953618; called by muse, mutect2, varscan2
- ERAP2 | c.1487G>A p.W496* | Nonsense Mutation (SNP) | VAF 49/72 reads (68%) | catalogued as COSV101163476; called by muse, mutect2, varscan2
- EXPH5 | c.3541C>T p.Q1181* | Nonsense Mutation (SNP) | VAF 42/57 reads (74%) | catalogued as COSV99760843; called by muse, mutect2, varscan2
- FAM153A | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.695); catalogued as rs762513804, COSV62363460; called by muse, mutect2, varscan2
- FBLN2 | c.2392G>A p.D798N | Missense Mutation (SNP) | VAF 99/139 reads (71%) | SIFT tolerated (0.38); PolyPhen benign (0.234); catalogued as rs763000970, COSV99851315; called by muse, mutect2, varscan2
- FBXO16 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1443494070, COSV60777775; called by muse, mutect2, varscan2
- FGF18 | c.387C>A p.F129L | Missense Mutation (SNP) | VAF 63/90 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99208533; called by muse, mutect2, varscan2
- FKBP1A | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 24/28 reads (86%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs760096309, COSV67750588, COSV67750705; called by muse, mutect2, varscan2
- FSHR | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); catalogued as rs1463482771, COSV100436456; called by muse, mutect2, varscan2
- FUT3 | c.668G>A p.G223E | Missense Mutation (SNP) | VAF 88/123 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99744205; called by muse, mutect2, varscan2
- GBF1 | c.5272C>T p.P1758S (on ENST00000369983 / NM_001377137.1; = p.P1757S on NM_004193.3) | Missense Mutation (SNP) | VAF 33/45 reads (73%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as COSV100890286; called by muse, mutect2, varscan2
- GLI2 | c.3734C>T p.A1245V (on ENST00000361492 / NM_001374353.1; = p.A1262V on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as COSV100082215; called by muse, mutect2, varscan2
- GRM8 | c.1203G>T p.K401N | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1281948271, COSV100280348; called by muse, mutect2
- HES6 | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as rs970410892, COSV56028794; called by muse, mutect2, varscan2
- HES6 | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV56028806; called by muse, mutect2, varscan2
- HIPK2 | c.2780C>T p.S927F | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100701992; called by muse, mutect2, varscan2
- HRNR | c.6020G>A p.G2007E | Missense Mutation (SNP) | VAF 46/232 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.052); catalogued as rs768694309, COSV100912828; called by mutect2, varscan2
- HS1BP3 | c.506T>G p.F169C | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100397749; called by muse, mutect2, varscan2
- HSD3B7 | c.298A>G p.T100A | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.89); PolyPhen benign (0.012); catalogued as COSV99287903; called by muse, mutect2, varscan2
- IGF2 | c.510C>A p.F170L (on ENST00000434045 / NM_001127598.3; = p.F114L on NM_000612.6) | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as COSV100323871; called by muse, mutect2, varscan2
- IRX5 | c.463A>G p.M155V | Missense Mutation (SNP) | VAF 107/253 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100315598; called by muse, mutect2, varscan2
- ITPR3 | c.1261C>T p.P421S | Missense Mutation (SNP) | VAF 60/165 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.159); catalogued as rs1282233387, COSV65416090; called by muse, mutect2, varscan2
- JADE3 | c.2396C>T p.P799L | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.727); catalogued as COSV99509489; called by muse, mutect2, varscan2
- KCNJ14 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs532186279, COSV60737950; called by muse, mutect2, varscan2
- KCNJ8 | c.428T>G p.F143C | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99557340; called by muse, mutect2, varscan2
- KDM4D | c.1012C>T p.R338C | Missense Mutation (SNP) | VAF 29/45 reads (64%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs782522479, COSV100624097; called by muse, mutect2, varscan2
- KLHDC2 | c.442C>T p.L148F | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs778374018, COSV100026855; called by muse, mutect2, varscan2
- KRT26 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100156381, COSV59412629; called by muse, mutect2, varscan2
- LARP7 | c.169C>T p.L57F | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100134957, COSV100135175; called by muse, mutect2, varscan2
- LMTK2 | c.3752C>T p.S1251F | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV52003719; called by muse, mutect2, varscan2
- LPAR4 | c.794A>G p.Y265C | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101425069; called by muse, mutect2, varscan2
- LUZP4 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 71/137 reads (52%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV100904829; called by muse, mutect2, varscan2
- MAP4K4 | c.3515A>T p.Q1172L (on ENST00000347699 / NM_001242559.2; = p.Q1098L on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV100153346; called by muse, mutect2, varscan2
- MARCHF10 | c.1431G>A p.M477I | Missense Mutation (SNP) | VAF 72/185 reads (39%) | SIFT tolerated (0.6); PolyPhen benign (0.038); catalogued as COSV100247794; called by muse, mutect2, varscan2
- MDGA2 | c.1300C>T p.P434S (on ENST00000399232 / NM_001113498.2; = p.P136S on NM_182830.4) | Missense Mutation (SNP) | VAF 70/134 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62079322; called by muse, mutect2, varscan2
- MED12 | c.5837C>T p.P1946L | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.067); catalogued as COSV100375765; called by muse, mutect2
- METTL7A | c.90G>A p.W30* | Nonsense Mutation (SNP) | VAF 72/100 reads (72%) | catalogued as COSV100153621; called by muse, mutect2, varscan2
- MICALL2 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV99875578; called by muse, mutect2, varscan2
- MPZL3 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 32/39 reads (82%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs760495054, COSV54054148, COSV54054264; called by muse, mutect2, varscan2
- MRPL15 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.593); catalogued as COSV99477483; called by muse, mutect2, varscan2
- MS4A1 | c.174G>A p.M58I | Missense Mutation (SNP) | VAF 79/103 reads (77%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as COSV61941858; called by muse, mutect2, varscan2
- MUC16 | c.32009T>C p.L10670P | Missense Mutation (SNP) | VAF 59/78 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV101197869; called by muse, mutect2, varscan2
- MUC16 | c.21386T>G p.L7129R | Missense Mutation (SNP) | VAF 79/104 reads (76%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.047); catalogued as COSV101197871; called by muse, mutect2, varscan2
- MUC5AC | c.14183C>A p.P4728H | Missense Mutation (SNP) | VAF 83/183 reads (45%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.664); catalogued as COSV100611300; called by muse, mutect2, varscan2
- MVB12A | c.665T>C p.L222P | Missense Mutation (SNP) | VAF 68/89 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100396386; called by muse, mutect2, varscan2
- NCOA3 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.298); catalogued as COSV100507062; called by muse, mutect2, varscan2
- NEK6 | c.678C>A p.F226L | Missense Mutation (SNP) | VAF 128/171 reads (75%) | SIFT tolerated (0.08); PolyPhen benign (0.33); catalogued as COSV100206609; called by muse, mutect2, varscan2
- NUTM2G | c.542G>A p.G181E | Missense Mutation (SNP) | VAF 68/172 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs758217302, COSV100672541; called by mutect2, varscan2
- OLFM4 | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 70/95 reads (74%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs751659629, COSV54580629; called by muse, mutect2, varscan2
- OR2T33 | c.339A>C p.L113F | Missense Mutation (SNP) | VAF 57/256 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100531533, COSV100531784; called by muse, mutect2, varscan2
- OR51D1 | c.828G>C p.R276S | Missense Mutation (SNP) | VAF 91/220 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100712339; called by muse, mutect2, varscan2
- OR51S1 | c.786G>A p.M262I | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs752318585, COSV59058657; called by muse, mutect2, varscan2
- OR8A1 | c.301C>T p.L101F | Missense Mutation (SNP) | VAF 48/63 reads (76%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.082); catalogued as rs773967118, COSV99420259; called by muse, mutect2, varscan2
- P2RY10 | c.432G>A p.W144* | Nonsense Mutation (SNP) | VAF 29/124 reads (23%) | catalogued as COSV99408916; called by muse, mutect2, varscan2
- PAPPA2 | c.536C>T p.T179I | Missense Mutation (SNP) | VAF 90/200 reads (45%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.007); catalogued as rs1366964105, COSV100866512, COSV62777007; called by muse, mutect2, varscan2
- PCDH12 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 58/80 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99185749; called by muse, mutect2, varscan2
- PDE1A | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100112721; called by muse, mutect2, varscan2
- PDGFD | c.739C>T p.R247* | Nonsense Mutation (SNP) | VAF 21/28 reads (75%) | catalogued as rs775015662, COSV56376373; called by muse, mutect2, varscan2
- PHF21B | c.1307G>A p.R436Q | Missense Mutation (SNP) | VAF 20/25 reads (80%) | SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as rs1245431766, COSV100503449; called by muse, mutect2, varscan2
- PHKA1 | c.3208G>A p.G1070R | Missense Mutation (SNP) | VAF 74/149 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59802053; called by muse, mutect2, varscan2
- PKD1L1 | c.5225C>T p.S1742F | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.104); catalogued as rs267601526, COSV99218235; called by muse, mutect2, varscan2
- PODXL | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 91/290 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV100539167; called by muse, mutect2, varscan2
- POLH | c.991C>G p.L331V | Missense Mutation (SNP) | VAF 61/141 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100947608; called by muse, mutect2, varscan2
- POM121L12 | c.143G>A p.G48D | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.685); catalogued as COSV101374832; called by muse, mutect2, varscan2
- PPP6R2 | c.2879C>A p.A960D (on ENST00000216061 / NM_001365836.1; = p.A926D on NM_014678.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/170 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); catalogued as COSV99323786; called by muse, mutect2, varscan2
- PRICKLE2 | c.1484C>T p.P495L (on ENST00000295902; = p.P439L on NM_198859.4) | Missense Mutation (SNP) | VAF 80/108 reads (74%) | SIFT tolerated (0.15); PolyPhen benign (0.197); catalogued as COSV99896540; called by muse, mutect2, varscan2
- PTEN | c.322C>T p.L108F | Missense Mutation (SNP) | VAF 72/109 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV64292642; called by muse, mutect2, varscan2
- RABGAP1 | c.1799C>T p.S600F | Missense Mutation (SNP) | VAF 70/100 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101016618; called by muse, mutect2
- RABGAP1 | c.1801C>T p.P601S | Missense Mutation (SNP) | VAF 72/104 reads (69%) | SIFT tolerated (0.44); PolyPhen benign (0.3); catalogued as COSV101016619; called by muse, mutect2
- RNF135 | c.1115G>A p.R372K | Missense Mutation (SNP) | VAF 50/65 reads (77%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV100103917; called by muse, mutect2, varscan2
- RYR1 | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 60/118 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs1443878514, COSV100614269; called by muse, mutect2, varscan2
- SCN4A | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101438300; called by muse, mutect2, varscan2
- SEMA3E | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.173); catalogued as rs763424945, COSV57087831; called by muse, mutect2, varscan2
- SHCBP1L | c.949C>T p.L317F | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.996); catalogued as COSV100840922; called by muse, mutect2, varscan2
- SHROOM2 | c.4140G>A p.R1380= | Splice Region (SNP) | VAF 13/34 reads (38%) | catalogued as COSV101098092; called by muse, mutect2, varscan2
- SIGLEC10 | c.1538T>C p.L513P | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100218414; called by muse, mutect2, varscan2
- SLAIN1 | c.766G>A p.E256K (on ENST00000466548; = p.E114K on NM_001040153.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/48 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV99934935; called by muse, mutect2, varscan2
- SLC25A1 | c.799C>G p.L267V | Missense Mutation (SNP) | VAF 18/271 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.062); catalogued as COSV99310856; called by muse, mutect2
- SLC39A12 | c.1985G>A p.W662* (on ENST00000377369 / NM_001145195.2; = p.W625* on NM_152725.3) | Nonsense Mutation (SNP) | VAF 40/56 reads (71%) | catalogued as COSV101069816; called by muse, mutect2, varscan2
- SLC41A1 | c.133G>T p.A45S | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100900319; called by muse, mutect2, varscan2
- SLCO6A1 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 158/224 reads (71%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs1407396276, COSV65806754, COSV65815279; called by muse, mutect2, varscan2
- SLIT2 | c.2333A>T p.H778L | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT tolerated (0.09); PolyPhen benign (0.1); catalogued as COSV99880457; called by muse, mutect2, varscan2
- SPTA1 | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100934130; called by muse, mutect2, varscan2
- TBX18 | c.1370A>T p.Y457F | Missense Mutation (SNP) | VAF 79/170 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0.351); catalogued as rs377103957, COSV100858395; called by muse, mutect2, varscan2
- TENT5D | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.013); catalogued as rs141007953, COSV57635765; called by muse, mutect2, varscan2
- TET3 | c.1787C>T p.A596V | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.06); catalogued as COSV99996142; called by muse, mutect2, varscan2
- TIGD2 | c.1162C>G p.L388V | Missense Mutation (SNP) | VAF 5/112 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.154); catalogued as COSV100392262; called by muse, mutect2
- TMEM168 | c.868C>T p.L290F | Missense Mutation (SNP) | VAF 162/619 reads (26%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.773); catalogued as rs749988695, COSV100454460, COSV57180585; called by muse, mutect2, varscan2
- TMEM266 | c.1394G>A p.R465Q | Missense Mutation (SNP) | VAF 72/212 reads (34%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs774278839, COSV101189552; called by muse, varscan2
- TNR | c.3829T>A p.S1277T | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV99687242; called by muse, mutect2, varscan2
- TRIM59 | c.980T>A p.L327* | Nonsense Mutation (SNP) | VAF 31/71 reads (44%) | catalogued as COSV100557408; called by muse, mutect2, varscan2
- TSHZ2 | c.2942C>T p.P981L | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.832); catalogued as COSV61589771; called by muse, mutect2, varscan2
- TSPYL6 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 57/179 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as COSV100336233; called by muse, mutect2, varscan2
- TTN | c.57874G>A p.E19292K (on ENST00000591111; = p.E11868K on NM_003319.4) | Missense Mutation (SNP) | VAF 18/45 reads (40%) | PolyPhen probably damaging (0.994); catalogued as COSV100592218; called by muse, mutect2, varscan2
- TYR | c.899A>C p.N300T | Missense Mutation (SNP) | VAF 90/127 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV99632880; called by muse, mutect2, varscan2
- USP9X | c.3110G>C p.R1037T | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); catalogued as COSV100198391; called by muse, mutect2
- VAC14 | c.2311G>A p.G771R | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.307); catalogued as rs761762197, COSV55753772; called by muse, mutect2, varscan2
- ZC4H2 | c.259C>A p.L87I | Missense Mutation (SNP) | VAF 87/167 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.096); catalogued as COSV100564696, COSV62006900; called by muse, mutect2, varscan2
- ZFHX3 | c.1255C>T p.P419S | Missense Mutation (SNP) | VAF 103/284 reads (36%) | SIFT tolerated (0.64); PolyPhen benign (0.125); catalogued as COSV99195061; called by muse, mutect2, varscan2
- ZNF280A | c.371G>A p.G124D | Missense Mutation (SNP) | VAF 54/214 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100130934; called by muse, mutect2, varscan2
- ZNF598 | c.2693C>T p.A898V | Missense Mutation (SNP) | VAF 138/392 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99937185; called by muse, mutect2, varscan2
- ZYX | c.1120C>T p.Q374* | Nonsense Mutation (SNP) | VAF 32/116 reads (28%) | catalogued as COSV99313486; called by muse, mutect2, varscan2
- CCL4 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 62/86 reads (72%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- HRNR | c.7430G>A p.G2477E | Missense Mutation (SNP) | VAF 28/185 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.092); called by mutect2, varscan2
- LHCGR | c.244_245del p.Q82Dfs*2 | Frame Shift Del (DEL) | VAF 16/186 reads (9%) | called by mutect2, pindel
- ABCB11 | c.3060G>A p.V1020= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs368622067; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRL2 | c.2778T>G p.A926= (on ENST00000370717 / NM_001366005.1; = p.A913= on NM_012302.4) | Silent (SNP) | VAF 63/90 reads (70%) | catalogued as COSV99586915; called by muse, mutect2, varscan2
- APOBEC3F | c.528T>C p.N176= | Silent (SNP) | VAF 250/768 reads (33%) | catalogued as rs1475320951, COSV100415094; called by muse, mutect2, varscan2
- ATP11C | c.741C>T p.L247= | Silent (SNP) | VAF 37/66 reads (56%) | catalogued as COSV100557254; called by muse, mutect2, varscan2
- BAHCC1 | c.7410C>T p.N2470= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV100311077; called by muse, mutect2, varscan2
- CABIN1 | c.3042C>T p.T1014= | Silent (SNP) | VAF 48/187 reads (26%) | catalogued as COSV99572623; called by muse, mutect2, varscan2
- CACNA1G | c.615G>A p.L205= | Silent (SNP) | VAF 64/161 reads (40%) | catalogued as COSV100661077; called by muse, mutect2, varscan2
- CCDC163 | c.414C>T p.S138= | Silent (SNP) | VAF 70/146 reads (48%) | catalogued as COSV100517015; called by muse, mutect2, varscan2
- CFAP94 | c.1872T>C p.F624= (on ENST00000320267 / NM_001352064.2; = p.F630= on NM_018272.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/61 reads (56%) | catalogued as COSV100208857; called by muse, mutect2
- CNNM1 | c.2622G>A p.E874= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as COSV100763759; called by muse, mutect2, varscan2
- CNOT6 | c.1671G>A p.R557= | Silent (SNP) | VAF 38/51 reads (75%) | catalogued as COSV99993374; called by muse, mutect2, varscan2
- CTC1 | c.2043C>T p.I681= | Silent (SNP) | VAF 182/255 reads (71%) | catalogued as COSV100236107; called by muse, mutect2, varscan2
- DOCK5 | c.5187C>T p.I1729= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as COSV99375924; called by muse, mutect2, varscan2
- DYM | c.633C>T p.T211= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as COSV99492481; called by muse, mutect2, varscan2
- ERN1 | c.1317C>T p.S439= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as COSV101458366; called by muse, mutect2, varscan2
- FAM160A2 | c.2700T>G p.A900= (on ENST00000449352 / NM_001098794.2; = p.A914= on NM_032127.4) | Silent (SNP) | VAF 86/206 reads (42%) | catalogued as rs751827058, COSV99791670; called by muse, mutect2, varscan2
- FKBP1A | c.120C>T p.S40= | Silent (SNP) | VAF 24/28 reads (86%) | catalogued as rs1231268182, COSV101098282; called by muse, mutect2, varscan2
- FOXJ1 | c.150C>T p.P50= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as rs1041745451, COSV99486558; called by muse, mutect2, varscan2
- GIPC1 | c.534C>T p.I178= | Silent (SNP) | VAF 120/159 reads (75%) | catalogued as rs768024211, COSV100600000; called by muse, mutect2, varscan2
- GLIPR1 | c.84C>T p.I28= | Silent (SNP) | VAF 44/100 reads (44%) | catalogued as rs775097349, COSV56990230, COSV56991321; called by muse, mutect2, varscan2
- GOLGA6L9 | c.138G>A p.R46= | Silent (SNP) | VAF 13/19 reads (68%) | called by muse, mutect2, varscan2
- GZMB | c.360G>A p.R120= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as rs1449016334, COSV99362160, COSV99362163; called by muse, mutect2, varscan2
- HMGCLL1 | c.978G>A p.L326= | Silent (SNP) | VAF 43/105 reads (41%) | catalogued as COSV51447968, COSV99231300; called by muse, mutect2, varscan2
- HYDIN | c.6201C>T p.I2067= | Silent (SNP) | VAF 42/115 reads (37%) | catalogued as rs779027520, COSV99991816; called by muse, mutect2, varscan2
- IGHG1 | c.765C>T p.F255= | Silent (SNP) | VAF 99/259 reads (38%) | called by muse, mutect2, varscan2
- KLK14 | c.10C>T p.L4= | Silent (SNP) | VAF 34/78 reads (44%) | catalogued as COSV99335599, COSV99335743; called by muse, mutect2, varscan2
- KLK14 | c.9C>T p.L3= | Silent (SNP) | VAF 34/79 reads (43%) | catalogued as COSV99335600; called by muse, mutect2, varscan2
- KRT16 | c.462G>A p.Q154= | Silent (SNP) | VAF 137/315 reads (43%) | catalogued as COSV100052767; called by muse, mutect2, varscan2
- LMTK2 | c.3753C>T p.S1251= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as rs148048560; called by muse, mutect2, varscan2
- NOTCH3 | c.4272C>T p.P1424= | Silent (SNP) | VAF 7/9 reads (78%) | catalogued as COSV99655646; called by muse, mutect2, varscan2
- OR10G8 | c.147G>A p.V49= | Silent (SNP) | VAF 92/127 reads (72%) | catalogued as rs992766885, COSV70909323; called by muse, mutect2, varscan2
- PCYT1B | c.720C>T p.Y240= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV100770436; called by muse, mutect2, varscan2
- PDPN | c.432C>T p.F144= (on ENST00000621990; = p.F220= on NM_006474.4) | Silent (SNP) | VAF 60/138 reads (43%) | called by muse, mutect2, varscan2
- PHKG2 | c.219C>T p.A73= | Silent (SNP) | VAF 31/78 reads (40%) | catalogued as COSV100079330; called by muse, mutect2, varscan2
- PIK3C2A | c.1659C>T p.L553= | Silent (SNP) | VAF 56/135 reads (41%) | catalogued as COSV99790152; called by muse, mutect2, varscan2
- PIWIL2 | c.981C>T p.F327= | Silent (SNP) | VAF 40/84 reads (48%) | catalogued as COSV100769164; called by muse, mutect2, varscan2
- PROC | c.135C>T p.S45= | Silent (SNP) | VAF 43/138 reads (31%) | catalogued as rs1558712038, COSV99300630; called by muse, mutect2, varscan2
- PRSS22 | c.864C>T p.I288= | Silent (SNP) | VAF 31/72 reads (43%) | catalogued as COSV99361747; called by muse, mutect2, varscan2
- RAPGEF4 | c.192G>C p.L64= | Silent (SNP) | VAF 11/189 reads (6%) | catalogued as COSV99909513; called by muse, mutect2
- RERGL | c.579G>A p.L193= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as COSV57464137; called by muse, mutect2, varscan2
- RYR1 | c.1197C>T p.A399= | Silent (SNP) | VAF 62/120 reads (52%) | catalogued as rs540083191, COSV100614270; called by muse, mutect2, varscan2
- SALL4 | c.144C>T p.N48= | Silent (SNP) | VAF 39/107 reads (36%) | catalogued as COSV99409105; called by muse, mutect2, varscan2
- SEZ6L | c.1032C>T p.T344= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as rs375660013; called by muse, mutect2, varscan2
- SLC28A1 | c.1857C>T p.C619= | Silent (SNP) | VAF 54/145 reads (37%) | catalogued as COSV99722452; called by muse, mutect2, varscan2
- SLFN13 | c.147C>T p.A49= | Silent (SNP) | VAF 19/159 reads (12%) | catalogued as rs539895892, COSV53195411, COSV99539680; called by muse, mutect2, varscan2
- SZT2 | c.1050C>T p.F350= | Silent (SNP) | VAF 94/251 reads (37%) | catalogued as COSV100986852; called by muse, mutect2, varscan2
- TAF1 | c.5523C>T p.S1841= (on ENST00000373790 / NM_138923.4; = p.S1862= on NM_004606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV99334307; called by muse, mutect2, varscan2
- TET3 | c.1788C>T p.A596= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV99996144; called by muse, mutect2, varscan2
- TMEM266 | c.1395G>A p.R465= | Silent (SNP) | VAF 71/212 reads (33%) | catalogued as rs1432622179, COSV101189553; called by muse, varscan2
- TMEM94 | c.942C>T p.L314= | Silent (SNP) | VAF 46/101 reads (46%) | catalogued as COSV100050055; called by muse, mutect2, varscan2
- TRPC7 | c.141C>T p.F47= | Silent (SNP) | VAF 97/142 reads (68%) | catalogued as COSV100725422; called by muse, mutect2, varscan2
- TTC6 | c.891C>T p.F297= (on ENST00000267368; = p.F1663= on NM_001310135.3) | Silent (SNP) | VAF 54/128 reads (42%) | catalogued as COSV99941498; called by muse, mutect2, varscan2
- ZNF16 | c.1446C>T p.I482= | Silent (SNP) | VAF 63/157 reads (40%) | catalogued as COSV99429380; called by muse, mutect2, varscan2
- ZNF598 | c.2694C>T p.A898= | Silent (SNP) | VAF 136/391 reads (35%) | catalogued as COSV99937184; called by muse, mutect2, varscan2
- ZNF775 | c.816C>T p.P272= | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as rs764137326, COSV100301306; called by muse, mutect2, varscan2
- ANKS1B | c.2420-19C>T | Intron (SNP) | VAF 26/88 reads (30%) | catalogued as COSV100227086; called by muse, mutect2, varscan2
- PRRC2B | c.5759-394C>T | Intron (SNP) | VAF 106/142 reads (75%) | catalogued as COSV100260817; called by muse, mutect2, varscan2
